Somatic mutation profile of tumor specimen TCGA-FG-A87Q-01A (aliquot TCGA-FG-A87Q-01A-11D-A36O-08) from TCGA case TCGA-FG-A87Q, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 61.8 years (22,565 days).
Specimen TCGA-FG-A87Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc1013e5-df72-4cf4-aa14-a18a99496d9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A87Q-10A (Blood Derived Normal), aliquot TCGA-FG-A87Q-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b894486c-64b1-46ab-8d4b-8f7cb01090ec

The open-access MAF lists 69 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 50, Silent 15, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 260/658 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.151); catalogued as COSV99289246; called by muse, mutect2, varscan2
- ACACB | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV100622629; called by muse, mutect2
- ADAM7 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs775659546, COSV51540835; called by muse, mutect2, varscan2
- ADGRV1 | c.3848T>C p.L1283P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV101315697; called by muse, mutect2, varscan2
- ANKAR | c.404C>G p.P135R | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99854067; called by muse, mutect2, varscan2
- ARHGAP5 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs78337553, COSV61533654; called by muse, mutect2
- ARHGEF4 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs201813341, COSV58122722; called by muse, mutect2, varscan2
- ASB9 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs746031297, COSV100995418; called by mutect2, varscan2
- ATP1B4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV54311354; called by muse, mutect2, varscan2
- BAAT | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99408430; called by muse, mutect2, varscan2
- BAHCC1 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV100311406; called by muse, mutect2, varscan2
- C8orf34 | c.1127T>G p.M376R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.974); catalogued as COSV100297860; called by muse, mutect2, varscan2
- CABLES2 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54156545; called by muse, mutect2, varscan2
- CACNA2D1 | c.2230T>C p.Y744H (on ENST00000356253 / NM_001366867.1; = p.Y732H on NM_000722.4) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV100666342; called by muse, mutect2, varscan2
- CCDC148 | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99320077; called by muse, mutect2, varscan2
- CDH9 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1340493492, COSV50251915; called by muse, mutect2, varscan2
- CELSR1 | c.3797T>C p.L1266P | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV99417607; called by muse, mutect2, varscan2
- COL7A1 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs762266379, COSV60405146; called by muse, mutect2, varscan2
- CSMD1 | c.7744G>A p.G2582S (on ENST00000520002; = p.G2581S on NM_033225.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as rs200463703, COSV100153026; called by muse, mutect2, varscan2
- ECHDC1 | c.104C>A p.S35Y (on ENST00000531967 / NM_001139510.1; = p.S29Y on NM_018479.3) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as COSV100541648; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1511A>G p.N504S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1341956402, COSV100668529; called by muse, mutect2, varscan2
- EGFR | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 99/1102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567477136, COSV51777313, COSV51843665; called by muse, mutect2
- ENPP5 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV100040402; called by muse, mutect2, varscan2
- GABRP | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs202158019; called by muse, mutect2, varscan2
- GOLM2 | c.1270C>G p.P424A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.917); catalogued as COSV100247724; called by muse, mutect2, varscan2
- HTR2C | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.293); catalogued as rs374923946, COSV99348758; called by muse, mutect2, varscan2
- KCNA10 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs576123443, COSV63904162; called by muse, mutect2, varscan2
- KCNT2 | c.2874C>G p.I958M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs1214879833, COSV99652640; called by muse, mutect2, varscan2
- KEL | c.759C>A p.Y253* | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as rs767815643, COSV100786970; called by muse, mutect2, varscan2
- L1TD1 | c.1598A>T p.Q533L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100776552; called by muse, mutect2, varscan2
- LRRC8A | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.137); catalogued as rs749079625, COSV52188258; called by muse, mutect2, varscan2
- ME2 | c.376A>C p.I126L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV100360709; called by muse, mutect2, varscan2
- MECOM | c.2846A>G p.E949G (on ENST00000468789 / NM_001105078.4; = p.E1137G on NM_004991.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.777); catalogued as rs1309579551, COSV99244417; called by muse, mutect2, varscan2
- NUMA1 | c.757A>G p.M253V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1335063274, COSV100705993; called by muse, mutect2
- OR4Q3 | c.739T>C p.S247P | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100056901; called by muse, mutect2, varscan2
- POGZ | c.3791T>C p.L1264S | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99304926; called by muse, mutect2, varscan2
- PRR23B | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs759081677, COSV61493889; called by muse, mutect2, varscan2
- PTCHD1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.146); catalogued as rs908889815, COSV65059191; called by muse, mutect2, varscan2
- PTGFR | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769693596, COSV100882265; called by muse, mutect2, varscan2
- RACK1 | c.147G>C p.E49D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100958666; called by muse, mutect2, varscan2
- RIMS2 | c.2882G>A p.R961Q (on ENST00000666250 / NM_001348490.2; = p.R769Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.755); catalogued as rs368813886; called by muse, mutect2, varscan2
- RPS6KA3 | c.243+1G>T p.X81_splice | Splice Site (SNP) | VAF 42/147 reads (29%) | catalogued as COSV101084260; called by muse, mutect2, varscan2
- RTL3 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV58185170; called by muse, mutect2, varscan2
- RTN1 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs770537807, COSV50720996; called by muse, mutect2
- SCRIB | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as COSV100252909; called by muse, mutect2
- TBXAS1 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as rs773843069, COSV99695082; called by muse, mutect2, varscan2
- THOP1 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs772371484, COSV57019253; called by muse, mutect2, varscan2
- TRPC7 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs955730809, COSV100725389, COSV100725616; called by muse, mutect2, varscan2
- TSSC4 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs776886790, COSV99329900; called by muse, varscan2
- TTN | c.74113C>A p.L24705M (on ENST00000591111; = p.L17281M on NM_003319.4) | Missense Mutation (SNP) | VAF 39/133 reads (29%) | PolyPhen possibly damaging (0.568); catalogued as COSV100603245; called by muse, mutect2, varscan2
- ZNF560 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs757976367, COSV56865089; called by muse, mutect2, varscan2
- ZNF609 | c.3488G>A p.R1163Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV58580131; called by muse, mutect2, varscan2
- MRPL35 | c.280del p.L94* | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel
- OR6C74 | c.837dup p.A280Cfs*21 | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- ABCA3 | c.159C>T p.N53= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs191085051, COSV57049259, COSV57053114; called by muse, mutect2, varscan2
- AHNAK2 | c.2583G>A p.P861= | Silent (SNP) | VAF 90/332 reads (27%) | catalogued as rs560264039, COSV60917184; called by muse, mutect2, varscan2
- CATSPERD | c.1914C>T p.F638= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs200017232, COSV58465004; called by muse, mutect2, varscan2
- CD19 | c.774G>A p.K258= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100218071; called by muse, mutect2, varscan2
- CD22 | c.2364G>A p.P788= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs530650512, COSV50050207; called by muse, mutect2, varscan2
- CHM | c.1908G>A p.S636= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1482216707, COSV100753134; called by muse, mutect2, varscan2
- CST4 | c.201G>A p.P67= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs191660510; called by muse, mutect2, varscan2
- DSC2 | c.1143G>A p.K381= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV51869246, COSV99199576; called by muse, mutect2, varscan2
- MS4A4A | c.294C>T p.S98= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs374259384; called by muse, mutect2, varscan2
- NPTX2 | c.846C>T p.I282= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs867398757, COSV99674720, COSV99674767; called by muse, mutect2, varscan2
- OR5D18 | c.660G>A p.A220= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs779827741, COSV61737938, COSV61738052; called by muse, mutect2, varscan2
- PHF1 | c.927T>G p.L309= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as COSV100992585; called by muse, mutect2
- RHBDD2 | c.510C>T p.L170= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV50088842, COSV99138231; called by muse, mutect2, varscan2
- TRPM5 | c.78C>T p.G26= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs759599505, COSV99329902; called by muse, mutect2, varscan2
- ZSCAN2 | c.1086C>T p.Y362= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as rs368304150; called by muse, mutect2, varscan2
